Somatic mutation profile of tumor specimen C3L-05290-01 (aliquot CPT0341190006) from CPTAC case C3L-05290, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.6 years (26,889 days).
Specimen C3L-05290-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab025360-81ea-4c2e-983e-fd9abd060a46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05290-31 (Blood Derived Normal), aliquot CPT0341290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e3848ec-31bd-4349-a339-a34645fd972e

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 27, Silent 11, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AMY1C | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 41/446 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs1380159596; called by muse, mutect2
- ANKRD17 | c.6454A>G p.T2152A | Missense Mutation (SNP) | VAF 85/406 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs534371235; called by muse, mutect2, varscan2
- ARHGAP44 | c.1466del p.R489Pfs*11 | Frame Shift Del (DEL) | VAF 56/314 reads (18%) | catalogued as COSV52388683; called by mutect2, pindel, varscan2
- CNTNAP5 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs774075892, COSV70510855; called by muse, mutect2, varscan2
- FAP | c.1968C>T p.Y656= | Splice Region (SNP) | VAF 35/187 reads (19%) | catalogued as rs201719538; called by muse, mutect2, varscan2
- MAP7D3 | c.2377G>T p.D793Y | Missense Mutation (SNP) | VAF 84/480 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV100286712; called by muse, mutect2, varscan2
- MYBPC3 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 59/315 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs551119259, CD0910614, CM1110434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR2E1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV64561655, COSV64562372; called by muse, mutect2
- OR14C36 | c.315dup p.V106Cfs*14 | Frame Shift Ins (INS) | VAF 107/312 reads (34%) | catalogued as rs761899382; called by mutect2, varscan2
- PELO | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 26/559 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.101); catalogued as COSV99252016; called by muse, mutect2
- PROM2 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763160335; called by muse, mutect2, varscan2
- SH3GL3 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1555424607; called by muse, mutect2
- TOGARAM1 | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs1158857788, COSV63892971; called by muse, mutect2, varscan2
- ZNF469 | c.10724G>A p.R3575Q (on ENST00000437464; = p.R3603Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as rs537930010; called by muse, mutect2
- ADAMTS3 | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ASB15 | c.1356C>A p.D452E | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2
- CAGE1 | c.1060A>G p.I354V (on ENST00000512086; = p.I218V on NM_205864.3) | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- CDKL3 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 43/416 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAB1 | c.1194A>G p.K398= | Splice Region (SNP) | VAF 34/172 reads (20%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 113/578 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PERM1 | c.1233T>G p.D411E | Missense Mutation (SNP) | VAF 86/416 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- PRPF4B | c.1654_1656dup p.Y552dup | In Frame Ins (INS) | VAF 44/284 reads (15%) | called by mutect2, pindel, varscan2
- SLIT2 | c.1007T>A p.I336N | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPARC | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA5L1 | c.446T>A p.V149E | Missense Mutation (SNP) | VAF 105/465 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SPHKAP | c.2055del p.H685Qfs*4 | Frame Shift Del (DEL) | VAF 77/406 reads (19%) | called by mutect2, pindel, varscan2
- SREBF2 | c.3146G>C p.R1049P | Missense Mutation (SNP) | VAF 75/604 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STAM | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TACC3 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TAS1R3 | c.202A>G p.N68D | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D16 | c.1280A>C p.D427A | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- TTLL1 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF735 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 127/399 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CEP85L | c.2043G>A p.E681= | Silent (SNP) | VAF 53/210 reads (25%) | called by muse, mutect2, varscan2
- CUBN | c.10728C>T p.N3576= | Silent (SNP) | VAF 50/293 reads (17%) | catalogued as rs368511477; called by muse, mutect2, varscan2
- DNAJC13 | c.87A>C p.S29= | Silent (SNP) | VAF 48/242 reads (20%) | called by muse, mutect2, varscan2
- DST | c.3825T>C p.H1275= (on ENST00000361203 / NM_001374722.1; = p.H949= on NM_001723.6) | Silent (SNP) | VAF 35/328 reads (11%) | catalogued as rs776305444; called by muse, mutect2, varscan2
- FKBP5 | c.33A>G p.E11= | Silent (SNP) | VAF 30/434 reads (7%) | called by muse, mutect2
- FNDC3B | c.2541G>A p.P847= | Silent (SNP) | VAF 70/319 reads (22%) | catalogued as rs147677058; called by muse, mutect2, varscan2
- MDH2 | c.894C>G p.G298= | Silent (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- MTOR | c.1935C>T p.S645= | Silent (SNP) | VAF 56/345 reads (16%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1725C>T p.G575= | Silent (SNP) | VAF 34/513 reads (7%) | catalogued as rs782143025, COSV65367026, COSV65368460; called by muse, mutect2
- SLC7A4 | c.63G>A p.L21= | Silent (SNP) | VAF 80/498 reads (16%) | called by muse, mutect2, varscan2
- TTC30A | c.663G>A p.Q221= | Silent (SNP) | VAF 71/416 reads (17%) | called by muse, mutect2, varscan2
